Gene-level copy-number profile of tumor specimen TCGA-85-A4CN-01A from TCGA case TCGA-85-A4CN, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 56.1 years (20,490 days).
Specimen TCGA-85-A4CN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.bc993354-907b-42b9-a06e-0a25c3f9119b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-A4CN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fe20322c-ad9e-4be6-96b0-560ef1b0b7d1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 28,339; copy number 2: 27,103; copy number 3: 3,419; copy number 4: 31; copy number 6: 913.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-A4CN-01A-11D-A24C-01): tumor purity 0.54, ploidy 1.56, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:40,010,999–40,847,158, 5 genes (within-gene range 0–1): DSCAM, MIR4760, DSCAM-AS1, AF064863.1, DSCAM-IT1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 913 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:146,909,685–147,370,656, 1 gene, copy number 6 (within-gene range 1–6): AC092957.1.
- chr3:147,276,768–198,222,513, 912 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 25,918. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
